Somatic mutation profile of tumor specimen ALCH-AEQZ-TTP1-A (aliquot ALCH-AEQZ-TTP1-A-3-0-D-A678-36) from ALCHEMIST case ALCH-AEQZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.3 years (20,924 days).
Specimen ALCH-AEQZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef480cf4-ee58-451f-b120-4a4f8b4e476d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEQZ-NB1-A (Blood Derived Normal), aliquot ALCH-AEQZ-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a868b45d-aaa8-4079-a88a-094b19e9d8aa

The open-access MAF lists 193 somatic variants for this specimen: 144 protein-altering or splice-affecting, 31 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 31, Nonsense Mutation 12, Intron 11, Splice Region 4, RNA 3, 5'Flank 3, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1673T>A p.L558H (on ENST00000399959; = p.L559H on NM_001356.5) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1064794993; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 40/194 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 45/234 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH3B2 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225048453; called by muse, mutect2, varscan2
- BTK | c.894+1G>T p.X298_splice | Splice Site (SNP) | VAF 54/134 reads (40%) | catalogued as CS012205, CS941431, CS973723; called by muse, mutect2, varscan2
- CACNA2D1 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV62380453; called by muse, mutect2, varscan2
- CCDC141 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV55373209; called by muse, mutect2, varscan2
- CDHR2 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV56143431; called by muse, mutect2
- CDX2 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as rs763499719; called by muse, mutect2, varscan2
- CHSY3 | c.2468G>A p.R823K | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100518562, COSV59274060; called by muse, mutect2
- CLTCL1 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs782112307, COSV54233833; called by muse, mutect2
- CRYGB | c.111G>C p.R37S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs139609998, COSV99649981; called by muse, mutect2, varscan2
- CT47B1 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs748670528, COSV100988953; called by muse, mutect2, varscan2
- CYP7B1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 57/567 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100041818; called by muse, mutect2
- DHX37 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV100439551; called by muse, varscan2
- DISP3 | c.2741G>T p.R914L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV99610322; called by mutect2, varscan2
- DYNC1H1 | c.2852G>T p.G951V | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV100794980; called by muse, mutect2, varscan2
- ERBB3 | c.1252A>T p.I418F | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57265195; called by muse, mutect2, varscan2
- FAT3 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53153357; called by muse, mutect2, varscan2
- FBN2 | c.2738G>T p.G913V | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52500447; called by muse, mutect2, varscan2
- FGF5 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56891761; called by muse, mutect2
- FLRT3 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1395820876, COSV99427382; called by muse, mutect2, varscan2
- GFRA1 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815810; called by muse, mutect2, varscan2
- HBG1 | c.316-6C>G | Splice Region (SNP) | VAF 11/167 reads (7%) | catalogued as rs757239069; called by muse, mutect2
- IGKV2D-26 | c.197G>T p.R66M | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1192271752; called by muse, mutect2, varscan2
- INO80D | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as rs368120505, COSV68958353; called by muse, mutect2, varscan2
- IRX2 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV57414295; called by muse, varscan2
- KCNU1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.166); catalogued as COSV67758618; called by muse, mutect2
- KCNU1 | c.2690C>A p.T897K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV67754452, COSV67759771; called by muse, mutect2, varscan2
- MTMR12 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1233404046; called by muse, mutect2, varscan2
- MYO1C | c.1663G>A p.V555M (on ENST00000648651 / NM_001080779.2; = p.V520M on NM_033375.5) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs747522942; called by mutect2, varscan2
- MYRIP | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as rs1160458604, COSV56879015; called by muse, mutect2, varscan2
- NCF2 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761796267; called by muse, mutect2, varscan2
- OBI1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | catalogued as COSV99932372; called by muse, mutect2
- OPN1SW | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs373496991; called by muse, mutect2, varscan2
- OR13A1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100981123; called by muse, mutect2
- OR1N1 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.827); catalogued as rs376776019, COSV59196043; called by muse, mutect2
- OR2T1 | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 10/125 reads (8%) | catalogued as COSV63541643; called by muse, mutect2
- PAQR3 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754070447; called by muse, mutect2
- PCDH11Y | c.2138C>T p.S713F (on ENST00000400457 / NM_032973.2; = p.S702F on NM_032971.3) | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs749522575; called by muse, mutect2, varscan2
- PEDS1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752714557, COSV59010316; called by muse, mutect2, varscan2
- PKD1L1 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.288); catalogued as rs1287239948; called by muse, mutect2, varscan2
- POSTN | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV65713212; called by muse, mutect2
- PRKAG3 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767771448; called by mutect2, varscan2
- RIMS1 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53436563; called by muse, mutect2, varscan2
- RYR2 | c.5422G>T p.D1808Y | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764565730, COSV63690938; called by muse, mutect2, varscan2
- SLC39A12 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV66200589; called by muse, varscan2
- SLC39A6 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.954); catalogued as rs1426168777; called by muse, mutect2, varscan2
- SLC9A6 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65787323; called by muse, mutect2, varscan2
- SLCO1C1 | c.827T>A p.L276H | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56868378, COSV56881916; called by mutect2, varscan2
- SRRM1 | c.43A>T p.N15Y | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60476500; called by muse, mutect2
- TBX15 | c.1555G>T p.G519* (on ENST00000369429 / NM_001330677.2; = p.G413* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 21/166 reads (13%) | catalogued as COSV99254864; called by muse, mutect2, varscan2
- TNN | c.2119G>T p.D707Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53432489, COSV53438890; called by muse, mutect2, varscan2
- UACA | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs753673926, COSV59854684; called by muse, mutect2
- ZNF100 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV59748517; called by muse, mutect2
- ZNF236 | c.4465G>A p.G1489S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as rs200399832; called by muse, mutect2, varscan2
- ZNF98 | c.440C>A p.T147K | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100757427, COSV99078222; called by muse, mutect2
- AASS | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 31/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ACSM1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ALDH8A1 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKIB1 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ARHGAP26 | c.1697A>T p.K566M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ATL3 | c.695dup p.L232Ffs*3 | Frame Shift Ins (INS) | VAF 16/153 reads (10%) | called by mutect2, pindel, varscan2
- C1QTNF9 | c.625A>T p.T209S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C3orf56 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.224); called by muse, varscan2
- CADPS2 | c.1225T>A p.W409R | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC7 | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CCL19 | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CD5L | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2
- CHD9 | c.7487C>G p.T2496R (on ENST00000398510 / NM_001382353.1; = p.T2480R on NM_025134.7) | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHST12 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLASP2 | c.2959G>C p.E987Q (on ENST00000359576; = p.E986Q on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CLCA4 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNNM4 | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CNOT2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNTN6 | c.2222G>T p.R741L | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COMMD7 | c.526+7C>T | Splice Region (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- CRACR2A | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- CSMD2 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- DCTN6 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.085); called by muse, mutect2
- DGKB | c.1334C>G p.P445R | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLAT | c.1102A>T p.K368* | Nonsense Mutation (SNP) | VAF 39/289 reads (13%) | called by muse, mutect2, varscan2
- DMD | c.7141G>T p.E2381* | Nonsense Mutation (SNP) | VAF 106/298 reads (36%) | called by muse, mutect2, varscan2
- DMD | c.2292+4G>T | Splice Region (SNP) | VAF 66/180 reads (37%) | called by muse, varscan2
- DMRTA1 | c.376T>C p.C126R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DNAH9 | c.10516G>C p.A3506P | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2
- DNAJC13 | c.1754T>A p.M585K | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ENC1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- FBN2 | c.2737G>T p.G913* | Nonsense Mutation (SNP) | VAF 56/233 reads (24%) | called by muse, mutect2, varscan2
- FBXO16 | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- GABRA3 | c.627dup p.G210Wfs*9 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by pindel, varscan2*
- GPR85 | c.330C>A p.F110L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- HAND1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IRS4 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KAT6A | c.4625C>T p.S1542F | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1549L | c.3634T>A p.F1212I (on ENST00000321505; = p.F1509I on NM_012194.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP21-2 | c.221G>T p.C74F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- LAMA1 | c.765A>T p.R255S | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LYST | c.2690C>T p.T897I | Missense Mutation (SNP) | VAF 188/649 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MEIS3 | c.254A>T p.D85V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MMAB | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MTERF3 | c.151A>G p.N51D | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH4 | c.1073C>A p.A358D | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- MYO1A | c.1755C>A p.Y585* | Nonsense Mutation (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- NCR1 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- NEK10 | c.1620T>A p.S540R | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- NRN1L | c.290C>G p.S97* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- OR1S2 | c.360T>A p.F120L | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- PAGE1 | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, varscan2
- PCDH15 | c.4256T>A p.L1419* | Nonsense Mutation (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- PHKB | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PI16 | c.261G>C p.E87D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PIK3CG | c.2706del p.F902Lfs*6 | Frame Shift Del (DEL) | VAF 36/256 reads (14%) | called by mutect2, pindel, varscan2
- POLE2 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 21/225 reads (9%) | called by muse, mutect2
- PRAMEF27 | c.142A>T p.R48W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- RBM44 | c.626C>T p.S209F (on ENST00000611254; = p.S843F on NM_001080504.2) | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RELN | c.6371A>C p.D2124A | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RHOJ | c.482T>A p.V161E | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RIMS2 | c.4366G>C p.E1456Q (on ENST00000666250 / NM_001348490.2; = p.E1027Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF169 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2
- RP1 | c.3455A>G p.K1152R | Missense Mutation (SNP) | VAF 99/569 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RUNX2 | c.1384G>T p.G462* (on ENST00000371438; = p.G440* on NM_001015051.3) | Nonsense Mutation (SNP) | VAF 25/173 reads (14%) | called by muse, mutect2, varscan2
- RXFP1 | c.1298T>A p.I433N | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SCN10A | c.1361A>T p.N454I | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SCN3A | c.4947G>T p.M1649I | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2
- SFT2D1 | c.410+7C>T | Splice Region (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- SLC5A4 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLITRK3 | c.2490A>G p.I830M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SNTG1 | c.978G>C p.W326C | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SNX30 | c.1194G>T p.R398S | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STAU1 | c.62T>G p.L21R | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.601); called by muse, mutect2
- STXBP5L | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNPO2 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, varscan2
- TCP1 | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TEP1 | c.3122C>T p.A1041V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- TRANK1 | c.5980G>T p.V1994L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TSPAN3 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by mutect2, varscan2
- VCAN | c.1070G>T p.S357I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- WDR35 | c.2204del p.G735Afs*4 (on ENST00000345530 / NM_001006657.2; = p.G724Afs*4 on NM_020779.4) | Frame Shift Del (DEL) | VAF 44/338 reads (13%) | called by mutect2, pindel, varscan2
- ZFP2 | c.862C>A p.H288N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF208 | c.1790T>A p.I597N | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.102); called by muse, varscan2
- ZNF579 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF714 | c.1289G>T p.C430F | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- ZNF716 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1260G>T p.L420= | Silent (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- ADGRG4 | c.5961A>T p.T1987= | Silent (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- AL592490.1 | c.1002A>T p.T334= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- BPTF | c.6702C>T p.A2234= | Silent (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- COL1A2 | c.1377C>T p.I459= | Silent (SNP) | VAF 79/405 reads (20%) | catalogued as rs770230919, COSV51957882, COSV51965060; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRB1 | c.3891C>T p.D1297= | Silent (SNP) | VAF 26/431 reads (6%) | catalogued as rs1053974422; called by muse, mutect2
- DOCK4 | c.4071C>T p.P1357= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV70236305, COSV70243898; called by muse, mutect2, varscan2
- DYSF | c.4893C>T p.F1631= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs151276652; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EIF3M | c.333C>T p.H111= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs752452780; called by muse, mutect2, varscan2
- F9 | c.880C>A p.R294= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs137852248, CM940592, CM940593; called by muse, mutect2, varscan2
- H3C1 | c.120C>T p.H40= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.1665C>T p.D555= | Silent (SNP) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- LGR5 | c.333T>A p.T111= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as COSV57007597; called by muse, mutect2
- MICB | c.288C>G p.L96= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- MSR1 | c.1242G>A p.L414= | Silent (SNP) | VAF 37/410 reads (9%) | called by muse, mutect2
- MYH2 | c.1158G>A p.K386= | Silent (SNP) | VAF 29/294 reads (10%) | called by muse, mutect2
- OR5F1 | c.666C>G p.L222= | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1098T>A p.V366= | Silent (SNP) | VAF 78/457 reads (17%) | called by muse, mutect2, varscan2
- PHF20 | c.1272G>C p.S424= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV59185191; called by muse, mutect2, varscan2
- PRKCSH | c.1221G>A p.E407= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs528536486; called by muse, mutect2, varscan2
- RAB2B | c.342C>T p.I114= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as rs1251795372; called by muse, mutect2, varscan2
- SEH1L | c.489A>T p.L163= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- SYT16 | c.888C>G p.L296= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV70854753; called by muse, mutect2, varscan2
- TACR3 | c.1059C>A p.P353= | Silent (SNP) | VAF 27/256 reads (11%) | called by muse, mutect2, varscan2
- TLCD4 | c.267C>T p.N89= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs200020245, COSV64632310; called by muse, mutect2
- TRANK1 | c.5979G>A p.G1993= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- UNC13A | c.3508C>A p.R1170= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99409824; called by muse, mutect2
- XRN1 | c.2013G>A p.L671= | Silent (SNP) | VAF 25/241 reads (10%) | called by muse, varscan2
- ZNF451 | c.2376C>G p.G792= | Silent (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- ZNF726 | c.1821C>T p.T607= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs764639555; called by muse, mutect2, varscan2
- ZNF776 | c.1473A>T p.G491= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- AF121898.1 | n.205+24554A>T | Intron (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- ASAH1 | c.174-1875C>A | Intron (SNP) | VAF 32/390 reads (8%) | called by muse, mutect2
- DDX11 | c.1369+37A>T | Intron (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- EGLN3 | c.*18C>A | 3'UTR (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-4685C>A | Intron (SNP) | VAF 29/242 reads (12%) | called by muse, mutect2, varscan2
- GYG2P1 | n.450+3903T>G | Intron (SNP) | VAF 3/13 reads (23%) | called by mutect2, varscan2
- LINC01100 | n.358C>G | RNA (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- LINC01619 | n.1233G>A | RNA (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2
- OR5E1P | n.499T>A | RNA (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- PTBP1 | c.1042-31C>G | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128128651 G>A | 5'Flank (SNP) | VAF 3/26 reads (12%) | called by muse, varscan2
- RPL26L1 | chr5:172958386 T>A | 5'Flank (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- SLIT2 | c.3088+77T>C | Intron (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2
- SULF1 | c.2285-15T>A | Intron (SNP) | VAF 23/188 reads (12%) | called by muse, mutect2, varscan2
- TAFA2 | c.385-10501G>A | Intron (SNP) | VAF 26/209 reads (12%) | catalogued as rs760649060; called by muse, mutect2, varscan2
- TRPM1 | c.3431-27G>A | Intron (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2
- ZNF41 | chrX:47483799 C>G | 5'Flank (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+431G>C | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
